Somatic mutation profile of tumor specimen 0DNJBB from CCDI case PBCBRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Soft tissue tumor, benign; Tissue or organ of origin: Spinal cord; Age at diagnosis: 17.4 years (6,357 days).
Specimen 0DNJBB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1158ca61-4e8a-400a-9e6e-51fdc78a34bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNJA5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dc3fc1a-fc77-4ecf-bef9-8b6969d5d678

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4A | c.711A>G p.L237= | Silent (SNP) | VAF 92/412 reads (22%) | catalogued as rs775482850; called by muse, mutect2, varscan2
- CELSR3 | c.9546G>A p.R3182= | Silent (SNP) | VAF 33/651 reads (5%) | called by muse, mutect2
